Somatic mutation profile of cancer-model specimen HCM-BROD-0781-C71-85A (3D Neurosphere, passage 15; aliquot HCM-BROD-0781-C71-85A-01D-A88G-36), derived from the primary tumor of HCMI case HCM-BROD-0781-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.0 years (18,265 days).
Specimen HCM-BROD-0781-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 15.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 345d24e6-fdef-47d0-80ad-d92dae110888.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0781-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0781-C71-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e574108f-160f-4800-9fb7-e6b3c1a89f04

The open-access MAF lists 62 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 11, Nonsense Mutation 2, In Frame Del 2, Frame Shift Del 2, Frame Shift Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 112/243 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 477/477 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALG9 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 204/417 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs1417298979; called by muse, mutect2, varscan2
- CCDC168 | c.6086G>A p.G2029D | Missense Mutation (SNP) | VAF 185/185 reads (100%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); catalogued as rs1476105876; called by muse, mutect2, varscan2
- DCLK3 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 47/755 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs767622640, COSV69362121; called by muse, mutect2
- DIAPH2 | c.1887A>C p.K629N | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61297808; called by muse, mutect2
- DOC2A | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.173); catalogued as rs1293139314; called by muse, mutect2, varscan2
- DSCAML1 | c.1999G>A p.A667T (on ENST00000321322; = p.A607T on NM_020693.4) | Missense Mutation (SNP) | VAF 152/311 reads (49%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.721); catalogued as rs777412471, COSV58389017; called by muse, mutect2, varscan2
- GLIS3 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs200476741; called by muse, mutect2, varscan2
- HECW1 | c.1816G>C p.V606L | Missense Mutation (SNP) | VAF 306/1039 reads (29%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV67821016; called by muse, mutect2, varscan2
- HELZ | c.2316G>T p.L772F | Missense Mutation (SNP) | VAF 100/251 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs79989726; called by muse, mutect2, varscan2
- HYDIN | c.5037+1G>T p.X1679_splice | Splice Site (SNP) | VAF 46/197 reads (23%) | catalogued as COSV59271019; called by muse, mutect2, varscan2
- JUP | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 173/373 reads (46%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs200019016, COSV60278185, COSV60279132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KAT2B | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 208/435 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as rs758526610, COSV55431684, COSV99769026; called by muse, mutect2, varscan2
- LILRB5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 399/784 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs923890744, COSV60259321; called by muse, mutect2, varscan2
- LRP2 | c.10651C>T p.R3551C | Missense Mutation (SNP) | VAF 108/302 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1188450012, COSV55567967; called by muse, mutect2, varscan2
- MUSK | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs773818596, COSV51878062; called by muse, mutect2, varscan2
- MYO1B | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 93/341 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV58437697; called by muse, mutect2, varscan2
- NF2 | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 176/201 reads (88%) | catalogued as CM961036, COSV58523422, COSV58524068; called by muse, mutect2, varscan2
- NLRP5 | c.2134C>A p.L712I | Missense Mutation (SNP) | VAF 100/485 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.338); catalogued as COSV66765867, COSV66767842; called by muse, mutect2, varscan2
- OR2L5 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 99/219 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1376403025, COSV62364299; called by muse, mutect2, varscan2
- PADI3 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 247/509 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as rs534887968; called by muse, varscan2
- SLCO2B1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 151/393 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.329); catalogued as rs145010543, COSV56932851; called by muse, mutect2
- SPTA1 | c.5377C>T p.R1793W | Missense Mutation (SNP) | VAF 249/469 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375618954; called by muse, mutect2, varscan2
- ATAD2B | c.1237A>C p.K413Q | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH8 | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 77/268 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- CDKN2C | c.171dup p.L58Tfs*2 | Frame Shift Ins (INS) | VAF 153/403 reads (38%) | called by mutect2, pindel, varscan2
- FAM120B | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 336/738 reads (46%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FAM120B | c.1615G>C p.E539Q | Missense Mutation (SNP) | VAF 247/493 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.311); called by muse, varscan2
- FLII | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 143/332 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- GPR34 | c.8G>C p.S3T | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HMCN2 | c.13538G>T p.G4513V | Missense Mutation (SNP) | VAF 184/385 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HOMEZ | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- HUWE1 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- KCNT2 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 173/332 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- KRT24 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 125/641 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NF1 | c.4094del p.C1365Sfs*13 (on ENST00000358273 / NM_001042492.3; = p.C1365Sfs*20 on NM_000267.3) | Frame Shift Del (DEL) | VAF 147/359 reads (41%) | called by mutect2, pindel, varscan2
- NUTM2F | c.1975G>A p.V659I | Missense Mutation (SNP) | VAF 181/446 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- SECISBP2L | c.1323del p.K442Nfs*11 (on ENST00000559471 / NM_001193489.2; = p.K397Nfs*11 on NM_014701.4) | Frame Shift Del (DEL) | VAF 180/447 reads (40%) | called by mutect2, pindel, varscan2
- SELE | c.718G>T p.V240F | Missense Mutation (SNP) | VAF 146/278 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SPAG6 | c.265_267del p.V89del | In Frame Del (DEL) | VAF 152/158 reads (96%) | called by mutect2, pindel, varscan2
- SPATA24 | c.175_177del p.K59del | In Frame Del (DEL) | VAF 152/370 reads (41%) | called by pindel, varscan2
- SYNJ1 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 111/637 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- TIMP2 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 234/524 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TLR4 | c.1581G>A p.M527I (on ENST00000355622 / NM_138554.5; = p.M487I on NM_003266.4) | Missense Mutation (SNP) | VAF 166/372 reads (45%) | SIFT tolerated (0.79); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TMC8 | c.1825C>G p.L609V | Missense Mutation (SNP) | VAF 264/584 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TRAPPC8 | c.3715A>C p.N1239H | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRIM42 | c.1779G>A p.W593* | Nonsense Mutation (SNP) | VAF 223/470 reads (47%) | called by muse, mutect2, varscan2
- UGT1A8 | c.631A>C p.I211L | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XPO4 | c.1153A>C p.S385R | Missense Mutation (SNP) | VAF 140/140 reads (100%) | SIFT tolerated (0.6); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- E2F8 | c.2265G>A p.G755= | Silent (SNP) | VAF 71/430 reads (17%) | catalogued as rs750195203; called by muse, mutect2, varscan2
- LRP2 | c.3039C>T p.C1013= | Silent (SNP) | VAF 251/397 reads (63%) | catalogued as rs200245838, COSV99786679; called by muse, mutect2, varscan2
- MAGEC3 | c.1254C>A p.S418= | Silent (SNP) | VAF 337/372 reads (91%) | called by muse, mutect2, varscan2
- P2RY2 | c.201G>A p.A67= | Silent (SNP) | VAF 293/646 reads (45%) | catalogued as rs543772574, COSV60778030; called by muse, mutect2, varscan2
- PPFIA1 | c.2694G>A p.V898= | Silent (SNP) | VAF 169/342 reads (49%) | called by muse, mutect2, varscan2
- PROKR1 | c.708C>A p.I236= | Silent (SNP) | VAF 120/460 reads (26%) | catalogued as rs747659156, COSV58136600; called by muse, mutect2, varscan2
- RAET1E | c.420C>T p.F140= | Silent (SNP) | VAF 309/664 reads (47%) | catalogued as COSV61722311; called by muse, mutect2
- RDH14 | c.234G>T p.A78= | Silent (SNP) | VAF 183/686 reads (27%) | catalogued as rs962695516; called by mutect2, varscan2
- RNF111 | c.1410C>G p.G470= | Silent (SNP) | VAF 160/309 reads (52%) | called by muse, mutect2, varscan2
- UBL4B | c.246C>T p.A82= | Silent (SNP) | VAF 229/506 reads (45%) | called by muse, mutect2, varscan2
- ZNF577 | c.963G>A p.T321= | Silent (SNP) | VAF 219/460 reads (48%) | catalogued as rs1460720311; called by muse, mutect2, varscan2
- IGFN1 | c.1241+56G>T | Intron (SNP) | VAF 242/473 reads (51%) | called by muse, mutect2, varscan2
